Somatic mutation profile of tumor specimen 2d266d2d-4bb3-436c-a3e7-06acb2 (aliquot 2d266d2d-4bb3-436c-a3e7-06acb2_D6) from CPTAC case 20CO003, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA.
Specimen 2d266d2d-4bb3-436c-a3e7-06acb2: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc29621f-76e8-4ede-bf3a-25acc139ac5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 9bd71309-d808-414e-8127-75b586 (Blood Derived Normal), aliquot 9bd71309-d808-414e-8127-75b586_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1f68713-bd5e-4c62-84a7-beb78e135a3f

The open-access MAF lists 2,229 somatic variants for this specimen: 1,495 protein-altering or splice-affecting, 476 silent, 258 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,077, Silent 476, Frame Shift Del 253, Intron 137, Nonsense Mutation 48, Frame Shift Ins 44, Splice Region 39, 3'UTR 38, RNA 31, 5'UTR 23, Splice Site 21, 5'Flank 17.

Variants (750 of 2,229; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL3 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.025); catalogued as rs764053964, COSV52459496, COSV52465227; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 49/382 reads (13%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- B2M | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 74/487 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, varscan2
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 53/309 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- CUL7 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 57/358 reads (16%) | catalogued as rs746333044, COSV54816389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHCR7 | c.453G>A p.W151* | Nonsense Mutation (SNP) | VAF 83/529 reads (16%) | catalogued as rs104894213, CM000681; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ESCO2 | c.760del p.T254Lfs*13 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as rs80359852; ClinVar: pathogenic; called by mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MSH2 | c.367-1G>A p.X123_splice | Splice Site (SNP) | VAF 14/86 reads (16%) | catalogued as rs267607925, CS057517; ClinVar: likely pathogenic; called by muse, varscan2
- MSH2 | c.2275G>T p.G759* | Nonsense Mutation (SNP) | VAF 49/241 reads (20%) | catalogued as rs63749854, CM042401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 20/180 reads (11%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 30/160 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRF1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs28933973, CM992951, COSV64615781; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RIT1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 7/116 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs869025191, CM149836, CM161971, CM161972, COSV64170884, COSV64171290, COSV64171744; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TEK | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 78/523 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs387906745, CM101736, COSV66230204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343583783; called by muse, mutect2, varscan2
- ABCA13 | c.9484C>T p.R3162* | Nonsense Mutation (SNP) | VAF 50/274 reads (18%) | catalogued as rs376273529; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCF3 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 53/335 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.959); catalogued as rs566108440; called by muse, mutect2, varscan2
- ABCG4 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 76/448 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); catalogued as rs751687769; called by muse, mutect2, varscan2
- ABHD8 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV99917289; called by muse, mutect2
- ABL1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1314838108; called by muse, mutect2, varscan2
- AC013489.1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs912398551, COSV51551210, COSV51554431; called by muse, mutect2, varscan2
- AC092143.1 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 173/1077 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs191908032, COSV100206157; called by muse, mutect2, varscan2
- ACACB | c.4336G>A p.V1446I | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.503); catalogued as rs1206360026; called by muse, mutect2, varscan2
- ACACB | c.5501G>A p.R1834H | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs369007554; called by muse, mutect2, varscan2
- ACIN1 | c.3164C>T p.T1055M | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs776620841; called by muse, varscan2
- ACTC1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 91/643 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs727505179, COSV51757913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN4 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 131/808 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs759411096, COSV99400054; called by muse, mutect2, varscan2
- ACVR2A | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV54020809; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM20 | c.68dup p.L23Ffs*42 | Frame Shift Ins (INS) | VAF 38/348 reads (11%) | catalogued as rs1301541036; called by mutect2, varscan2
- ADAM28 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1288762925, COSV56101145; called by muse, mutect2, varscan2
- ADAMTS3 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54398566; called by muse, mutect2, varscan2
- ADAMTS4 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as rs780697413, COSV63490428; called by muse, mutect2, varscan2
- ADAMTSL4 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs747678360; called by muse, mutect2, varscan2
- ADAT3 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.024); catalogued as rs371998480; called by muse, mutect2, varscan2
- ADCY3 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777689844, COSV53171677; called by muse, mutect2, varscan2
- ADCY4 | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs767502998, COSV60254120; called by muse, mutect2, varscan2
- ADCY8 | c.3500C>T p.T1167M | Missense Mutation (SNP) | VAF 58/541 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356343883, COSV53897190; called by muse, mutect2, varscan2
- ADCY9 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs772697228, COSV53574136; called by muse, mutect2, varscan2
- ADGRA1 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.408); catalogued as COSV66927501; called by muse, mutect2, varscan2
- ADGRB1 | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1228759534, COSV60099254, COSV60103408; called by muse, mutect2, varscan2
- ADSL | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760629234; called by muse, mutect2, varscan2
- AGO3 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs1557696520, COSV55797754; called by muse, mutect2, varscan2
- AGRN | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 70/439 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as rs143976046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AJM1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 92/357 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1323738184; called by muse, mutect2, varscan2
- AKAP12 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs199646466; called by muse, mutect2, varscan2
- ALDH3A1 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 70/419 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs545679214, COSV56734632; called by muse, mutect2, varscan2
- ALOXE3 | c.1681T>G p.S561A | Missense Mutation (SNP) | VAF 75/501 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs552678986; called by muse, mutect2, varscan2
- ALS2CL | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs554056115, COSV100015035, COSV59674084; called by muse, mutect2, varscan2
- ALX3 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776967754, COSV63928742; called by muse, mutect2, varscan2
- AMZ1 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 95/535 reads (18%) | catalogued as rs1479125511; called by muse, mutect2, varscan2
- ANAPC1 | c.5507G>A p.R1836Q | Missense Mutation (SNP) | VAF 25/285 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1291114525; called by muse, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANKRD62 | c.1439del p.K480Sfs*5 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs774510795; called by mutect2, varscan2
- ANO9 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs1406807973; called by muse, mutect2, varscan2
- ANXA6 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199949353, COSV100636950; called by muse, mutect2, varscan2
- ANXA9 | c.174C>T p.G58= | Splice Region (SNP) | VAF 7/58 reads (12%) | catalogued as rs776695364; called by mutect2, varscan2
- APBA1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV55222939; called by muse, mutect2, varscan2
- APC | c.3114del p.G1039Efs*17 | Frame Shift Del (DEL) | VAF 41/312 reads (13%) | catalogued as CD067519; called by mutect2, pindel, varscan2
- APC | c.4280del p.P1427Lfs*46 | Frame Shift Del (DEL) | VAF 29/203 reads (14%) | catalogued as COSV57384647; called by mutect2, pindel, varscan2
- APLP1 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs752685508; called by muse, mutect2, varscan2
- APOL1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.518); catalogued as rs757047533, COSV59869222, COSV59869546; called by muse, mutect2, varscan2
- APPL1 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs143447963; called by muse, mutect2, varscan2
- AR | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.926); catalogued as rs775502238, CM053773; called by muse, mutect2, varscan2
- ARAP1 | c.1744G>A p.A582T (on ENST00000393609 / NM_001040118.2; = p.A337T on NM_015242.4) | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs369299440; called by muse, mutect2, varscan2
- ARAP2 | c.3328G>A p.A1110T | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1401782755; called by muse, mutect2, varscan2
- AREL1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.91); catalogued as rs745937103, COSV62666402; called by muse, mutect2, varscan2
- ARHGAP1 | c.819C>T p.H273= | Splice Region (SNP) | VAF 42/272 reads (15%) | catalogued as rs1182276493; called by muse, mutect2, varscan2
- ARHGAP21 | c.4906G>A p.D1636N | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748733945; called by muse, mutect2, varscan2
- ARHGAP32 | c.4193G>A p.R1398H (on ENST00000310343 / NM_001378025.1; = p.R1049H on NM_014715.4) | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs745938491, COSV100089258; called by muse, mutect2, varscan2
- ARHGEF11 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs765349041; called by muse, mutect2, varscan2
- ARID3C | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99427104; called by muse, mutect2, varscan2
- ARPIN | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 59/329 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV62590369; called by muse, mutect2, varscan2
- ART3 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.097); catalogued as rs201551056; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 48/108 reads (44%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASCC3 | c.5024A>G p.Y1675C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201404914; called by muse, mutect2, varscan2
- ASCC3 | c.1058del p.K353Rfs*6 | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | catalogued as rs1361297712; called by mutect2, pindel, varscan2
- ASH1L | c.6931C>T p.R2311W (on ENST00000368346 / NM_001366177.2; = p.R2306W on NM_018489.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs142371619; called by muse, mutect2, varscan2
- ASS1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 100/361 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs764331417, COSV61689809; called by muse, mutect2, varscan2
- ASXL3 | c.6646C>T p.R2216W | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs935514846, COSV52461639, COSV52467723; called by muse, mutect2, varscan2
- ATAD3A | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs368185567, COSV59235816; called by muse, mutect2, varscan2
- ATF7 | c.996dup p.R333Afs*8 (on ENST00000548446 / NM_001366555.2; = p.R322Afs*8 on NM_006856.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 26/151 reads (17%) | catalogued as rs1349165302; called by mutect2, pindel, varscan2
- ATM | c.3614G>A p.R1205H | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs769106895, COSV99069642; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ATP1B3 | c.139del p.Y47Mfs*42 | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | catalogued as COSV53949154; called by mutect2, pindel, varscan2
- ATP2A1 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 97/594 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1446136088, COSV63921332; called by muse, mutect2, varscan2
- ATP2B4 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs773914510, COSV100396943; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs781278654; called by mutect2, varscan2
- ATP9B | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.953); catalogued as rs371121796; called by mutect2, varscan2
- ATXN10 | c.1356del p.V453Wfs*12 | Frame Shift Del (DEL) | VAF 50/294 reads (17%) | catalogued as COSV53294301; called by mutect2, pindel, varscan2
- AUH | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs776281357, COSV100342541; called by muse, mutect2, varscan2
- AVEN | c.717del p.I241Sfs*4 | Frame Shift Del (DEL) | VAF 13/130 reads (10%) | catalogued as rs759306134, COSV60734589; called by mutect2, pindel, varscan2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 32/233 reads (14%) | catalogued as rs770737105, COSV57327371; called by mutect2, pindel, varscan2
- B4GAT1 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as rs777675589; called by muse, mutect2, varscan2
- BAHCC1 | c.5989G>A p.V1997M | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV57033849; called by muse, mutect2, varscan2
- BAZ1A | c.3040C>T p.R1014W | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs151068420; called by muse, mutect2, varscan2
- BCAT2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs372825449, COSV60271778; called by muse, mutect2, varscan2
- BCL11A | c.1175C>T p.T392M (on ENST00000335712 / NM_001365609.1; = p.T426M on NM_018014.4) | Missense Mutation (SNP) | VAF 80/522 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59633229; called by muse, mutect2, varscan2
- BCO2 | c.1694C>A p.P565H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63062689; called by muse, mutect2, varscan2
- BEST3 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753205163; called by muse, mutect2, varscan2
- BICDL1 | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs201376334; called by muse, varscan2
- BICDL1 | c.1666del p.D556Mfs*57 | Frame Shift Del (DEL) | VAF 25/162 reads (15%) | catalogued as rs755289629, COSV99984716; called by pindel, varscan2
- BICRA | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1568569209; called by muse, mutect2, varscan2
- BLZF1 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774681975; called by muse, mutect2, varscan2
- BMP1 | c.1766-4G>A | Splice Region (SNP) | VAF 37/269 reads (14%) | catalogued as rs201714147; called by muse, mutect2, varscan2
- BRAP | c.634-2A>G p.X212_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100553922; called by mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 11/79 reads (14%) | catalogued as rs749043197; called by mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 32/198 reads (16%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 22/130 reads (17%) | catalogued as rs751388819; called by mutect2, varscan2
- C11orf68 | c.643C>T p.R215W (on ENST00000530188; = p.R256W on NM_031450.4) | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs959219683; called by muse, mutect2, varscan2
- C19orf67 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs1363761178; called by muse, mutect2
- C2CD3 | c.2375A>G p.N792S | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs369089792; called by muse, mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs747496393; called by mutect2, pindel, varscan2
- C4BPA | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as rs372190373; called by mutect2, varscan2
- C7orf31 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 30/150 reads (20%) | catalogued as rs756961650, COSV52219692; called by muse, mutect2, varscan2
- CACNA1G | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs753325385; called by muse, mutect2, varscan2
- CADPS | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs757880751, COSV51868936; called by muse, mutect2, varscan2
- CALHM3 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs942637677; called by muse, mutect2, varscan2
- CAMKK1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs899292758; called by muse, mutect2, varscan2
- CAMKK2 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs766586427; called by muse, mutect2, varscan2
- CAPRIN1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 35/148 reads (24%) | catalogued as rs1322289677; called by muse, mutect2, varscan2
- CARD10 | c.655_657del p.E219del | In Frame Del (DEL) | VAF 32/158 reads (20%) | catalogued as rs1217698567; called by pindel, varscan2
- CARMIL2 | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV58024339; called by muse, mutect2, varscan2
- CASKIN1 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs954454316; called by muse, mutect2, varscan2
- CATSPER4 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 90/495 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199726912; called by muse, mutect2, varscan2
- CBY3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.856); catalogued as rs925910983; called by muse, mutect2, varscan2
- CCAR2 | c.1249dup p.R417Pfs*49 | Frame Shift Ins (INS) | VAF 28/130 reads (22%) | catalogued as rs756536005; called by mutect2, varscan2
- CCDC153 | c.599dup p.G201Wfs*9 | Frame Shift Ins (INS) | VAF 22/124 reads (18%) | catalogued as rs745729530; called by mutect2, varscan2
- CCDC168 | c.5930T>C p.M1977T | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.028); catalogued as rs1306411714; called by muse, mutect2, varscan2
- CCDC178 | c.1279del p.T427Hfs*23 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs776882105; called by mutect2, pindel, varscan2
- CCDC30 | c.530G>A p.R177Q (on ENST00000340612; = p.R134Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs771159252, COSV59605287; called by mutect2, varscan2
- CCDC40 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 86/534 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774273644, COSV100884311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC74B | c.39del p.S14Afs*21 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | catalogued as rs1198697781; called by mutect2, varscan2
- CD248 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs573402557, COSV60937021; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 21/132 reads (16%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDCA3 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs1220104412; called by muse, mutect2, varscan2
- CDH23 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs775781391; called by muse, mutect2, varscan2
- CDKN2D | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs577358923, COSV57264484; called by muse, mutect2, varscan2
- CECR2 | c.2792G>A p.R931H (on ENST00000342247 / NM_001290047.2; = p.R748H on NM_001290046.1) | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs371679902, COSV52838633; called by muse, mutect2, varscan2
- CELA2A | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as rs149636986; called by muse, mutect2, varscan2
- CENPK | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs755218264; called by muse, mutect2, varscan2
- CEP135 | c.3095del p.N1032Tfs*18 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | catalogued as COSV57258460; called by mutect2, pindel, varscan2
- CEP170 | c.2597_2599del p.S866del | In Frame Del (DEL) | VAF 24/208 reads (12%) | catalogued as rs760403823; called by pindel, varscan2
- CERK | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs138181197; called by muse, varscan2
- CFAP45 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1038417813, COSV63648600; called by muse, mutect2, varscan2
- CFAP54 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1419429071; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 57/338 reads (17%) | catalogued as rs778664468; called by mutect2, varscan2
- CFTR | c.913T>G p.F305V | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs201885470, CM067754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD5 | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104389859; called by muse, mutect2, varscan2
- CHD5 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1000382138; called by muse, mutect2, varscan2
- CHD9 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs181647712, COSV54610812; called by muse, mutect2, varscan2
- CHD9 | c.7291del p.R2431Gfs*8 (on ENST00000398510 / NM_001382353.1; = p.R2415Gfs*8 on NM_025134.7) | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs748826986; called by mutect2, pindel, varscan2
- CHL1 | c.3136C>T p.R1046C (on ENST00000397491 / NM_001253387.1; = p.R1062C on NM_006614.4) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs555557287, COSV56600202; called by muse, mutect2, varscan2
- CHRFAM7A | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222637529, COSV100241724; called by muse, mutect2, varscan2
- CIITA | c.1962dup p.G655Rfs*94 | Frame Shift Ins (INS) | VAF 80/512 reads (16%) | catalogued as rs778982759; called by mutect2, varscan2
- CIZ1 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as rs770784977, COSV104373916, COSV52975055; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 40/229 reads (17%) | catalogued as rs752250702; called by mutect2, varscan2
- CLCN2 | c.2144-1G>T p.X715_splice | Splice Site (SNP) | VAF 34/240 reads (14%) | catalogued as COSV99658279; called by muse, mutect2, varscan2
- CLIP1 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100212570; called by muse, mutect2, varscan2
- CLTCL1 | c.296T>C p.M99T | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs1555971483; called by muse, mutect2, varscan2
- CNNM4 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 59/449 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362245527, CM160805; called by muse, mutect2, varscan2
- CNTN1 | c.2594C>T p.S865L | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.174); catalogued as rs761108267, COSV100751888, COSV61647110; called by muse, mutect2, varscan2
- CNTNAP1 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.094); catalogued as rs147433219; called by muse, mutect2, varscan2
- CNTRL | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1298286719; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 41/130 reads (32%) | catalogued as rs374805044; called by mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs748995811; called by mutect2, varscan2
- COL11A1 | c.1635dup p.P546Afs*9 | Frame Shift Ins (INS) | VAF 17/106 reads (16%) | catalogued as rs779795373; called by mutect2, varscan2
- COL14A1 | c.4236G>A p.P1412= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as rs146129118; called by muse, mutect2, varscan2
- COL4A3 | c.4717G>A p.G1573S | Missense Mutation (SNP) | VAF 88/483 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs761262391; called by muse, mutect2, varscan2
- COL5A1 | c.2582del p.P861Lfs*213 | Frame Shift Del (DEL) | VAF 86/393 reads (22%) | catalogued as COSV65673893; called by mutect2, pindel, varscan2
- COL5A3 | c.1442dup p.G482Wfs*66 | Frame Shift Ins (INS) | VAF 17/101 reads (17%) | catalogued as rs774328155; called by mutect2, pindel, varscan2
- COPG1 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs369168388; called by muse, mutect2, varscan2
- CORO6 | c.970A>G p.R324G | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61470690; called by muse, mutect2, varscan2
- CPA1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs782142627, COSV50569170; called by muse, mutect2, varscan2
- CPLX4 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs752019452, COSV55313481; called by muse, mutect2, varscan2
- CPNE5 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1250710190; called by muse, mutect2, varscan2
- CROCC2 | c.3436del p.D1146Tfs*13 | Frame Shift Del (DEL) | VAF 39/252 reads (15%) | catalogued as rs1255916134; called by mutect2, pindel, varscan2
- CRTAC1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs374956458; called by muse, mutect2, varscan2
- CRYGB | c.251del p.P84Rfs*8 | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | catalogued as rs1559328208, COSV53679868; called by mutect2, pindel, varscan2
- CSH1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1370328347, COSV60242255; called by muse, varscan2
- CSMD2 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771665223, COSV99594667; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 34/164 reads (21%) | catalogued as rs766438669; called by mutect2, varscan2
- CSNK2A2 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1374223667, COSV52642966; called by muse, mutect2, varscan2
- CTAGE9 | c.176del p.L59Cfs*27 | Frame Shift Del (DEL) | VAF 82/450 reads (18%) | catalogued as rs752217831; called by mutect2, varscan2
- CTDNEP1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs1338391950; called by muse, mutect2, varscan2
- CTNNBL1 | c.1392+1G>A p.X464_splice | Splice Site (SNP) | VAF 39/234 reads (17%) | catalogued as rs766206506, COSV63744937; called by muse, mutect2, varscan2
- CXXC5 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 70/418 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.119); catalogued as rs764635929; called by muse, mutect2, varscan2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 23/196 reads (12%) | catalogued as rs775988957; called by mutect2, pindel, varscan2
- CYBC1 | c.298+8G>A | Splice Region (SNP) | VAF 15/93 reads (16%) | catalogued as rs538937116; called by muse, mutect2, varscan2
- CYP2E1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs533468318, COSV53315477; called by muse, mutect2, varscan2
- CYP46A1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55897113, COSV99952681; called by muse, mutect2, varscan2
- CYP4F22 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 68/434 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs767352854, CM162735, COSV54106743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAB2IP | c.2674C>T p.R892* (on ENST00000408936; = p.R864* on NM_032552.3) | Nonsense Mutation (SNP) | VAF 49/422 reads (12%) | catalogued as COSV52253980; called by muse, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | catalogued as rs751187768; called by mutect2, varscan2
- DACT2 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs371504350; called by muse, mutect2, varscan2
- DCHS2 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59726358; called by muse, mutect2, varscan2
- DDX42 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as COSV63790195; called by muse, mutect2, varscan2
- DENND4B | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs776450667; called by muse, mutect2, varscan2
- DENND4B | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs768543038, COSV63412376; called by muse, mutect2, varscan2
- DEPDC5 | c.2687G>A p.R896H (on ENST00000400246; = p.R965H on NM_014662.5) | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.267); catalogued as rs762596342, COSV99836273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX8 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs550472362; called by mutect2, varscan2
- DIAPH2 | c.2719G>T p.V907F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61268566; called by muse, mutect2, varscan2
- DIPK1A | c.1022_1023del p.T341Rfs*3 | Frame Shift Del (DEL) | VAF 20/206 reads (10%) | catalogued as rs1201428982; called by pindel, varscan2
- DIS3 | c.1881del p.A629Lfs*2 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as rs774491006; called by mutect2, pindel, varscan2
- DISP2 | c.1758G>A p.M586I | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs771651961; called by muse, mutect2, varscan2
- DIXDC1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 45/235 reads (19%) | catalogued as COSV100180375; called by muse, mutect2, varscan2
- DKK2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1379480164, COSV53394626; called by muse, mutect2, varscan2
- DLG5 | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as COSV64947871; called by muse, mutect2, varscan2
- DLGAP2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1220577024, COSV70099055; called by muse, mutect2, varscan2
- DNAH12 | c.3145C>T p.R1049* (on ENST00000351747; = p.R1072* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 28/158 reads (18%) | catalogued as rs1275098564, COSV61058837; called by muse, mutect2, varscan2
- DNAH2 | c.4483C>T p.R1495W | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs776753676; called by muse, mutect2, varscan2
- DNAH2 | c.6580G>A p.E2194K | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376871028; called by muse, mutect2, varscan2
- DNAH3 | c.11843G>A p.R3948H | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756913147; called by muse, mutect2, varscan2
- DNAJB1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV54316447; called by muse, mutect2, varscan2
- DNAJB6 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs1381979382; called by muse, mutect2, varscan2
- DNAJC11 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs748488397; called by muse, mutect2, varscan2
- DNAJC5B | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs188306348; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK6 | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as rs374437993; called by muse, mutect2, varscan2
- DOCK8 | c.4341G>A p.A1447= | Splice Region (SNP) | VAF 78/409 reads (19%) | catalogued as rs144133844; called by muse, mutect2, varscan2
- DPH2 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs751321281, COSV99356283; called by muse, mutect2, varscan2
- DPYSL2 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs374825617; called by muse, mutect2
- DPYSL5 | c.988A>C p.T330P | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV56514473; called by muse, mutect2, varscan2
- DRC7 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371507183; called by muse, mutect2, varscan2
- DROSHA | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.236); catalogued as rs369576938; called by muse, mutect2, varscan2
- DSP | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs868293429, COSV101131652; called by muse, mutect2, varscan2
- DST | c.2342C>T p.A781V (on ENST00000361203 / NM_001374722.1; = p.A455V on NM_001723.6) | Missense Mutation (SNP) | VAF 83/388 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1043850457; called by muse, mutect2, varscan2
- DTNB | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs764358672, COSV56480059; called by muse, mutect2, varscan2
- DVL2 | c.1801del p.A601Qfs*80 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as rs745455027; called by mutect2, pindel, varscan2
- DYNC1I1 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1381436803, COSV61458321; called by muse, mutect2, varscan2
- ECM1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 57/377 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV60872772; called by muse, mutect2, varscan2
- EDC4 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1294152714; called by muse, mutect2, varscan2
- EEF1D | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs761746722, COSV57819237; called by muse, mutect2, varscan2
- EGFLAM | c.1097dup p.S367Lfs*12 | Frame Shift Ins (INS) | VAF 36/266 reads (14%) | catalogued as rs773311790; called by mutect2, varscan2
- EGR3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 88/405 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as COSV100416307; called by muse, mutect2, varscan2
- ELAC1 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774952153; called by muse, mutect2
- ELANE | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV52255056; called by muse, mutect2, varscan2
- ELP1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs374814563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EMILIN1 | c.1386del p.R463Gfs*98 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as rs753533275; called by mutect2, pindel
- ENOX2 | c.282G>T p.M94I (on ENST00000338144 / NM_001382520.1; = p.M65I on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV100584543; called by muse, mutect2, varscan2
- EOGT | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs779799662, COSV55151647; called by muse, mutect2, varscan2
- EP400 | c.4667C>T p.S1556L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs945781301; called by muse, mutect2, varscan2
- EPG5 | c.4771G>A p.G1591S | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.372); catalogued as rs370120497; called by muse, mutect2, varscan2
- EPHA6 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1158291218, COSV67558239; called by muse, mutect2, varscan2
- EPS8L1 | c.2065G>A p.V689M (on ENST00000201647 / NM_133180.3; = p.V562M on NM_017729.3) | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99136145; called by muse, mutect2, varscan2
- ERBB3 | c.1479C>T p.C493= | Splice Region (SNP) | VAF 94/472 reads (20%) | catalogued as rs754618467; called by muse, mutect2, varscan2
- ESF1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1277847783, COSV52520081; called by muse, mutect2, varscan2
- ESR1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.818); catalogued as rs373558014; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 38/174 reads (22%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRRB | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 71/434 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs750798786, CM128420; called by muse, mutect2, varscan2
- ESS2 | c.617T>C p.I206T | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs778756650; called by muse, mutect2, varscan2
- EXOC5 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as rs1478637141, COSV61772317; called by muse, mutect2, varscan2
- EXOSC1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs903760300, COSV58355560; called by muse, mutect2, varscan2
- EXPH5 | c.1319A>G p.D440G | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1176904611; called by muse, mutect2, varscan2
- EXTL1 | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs752454839; called by muse, mutect2, varscan2
- FAAP100 | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs772479870, COSV59885625; called by muse, mutect2, varscan2
- FABP12 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 46/223 reads (21%) | catalogued as rs555788593; called by muse, mutect2, varscan2
- FAF2 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56132991; called by muse, mutect2, varscan2
- FAM20C | c.800dup p.T268Hfs*31 | Frame Shift Ins (INS) | VAF 34/184 reads (18%) | catalogued as rs750171507; called by mutect2, pindel, varscan2
- FAM71E2 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.748); catalogued as rs758250148; called by muse, mutect2, varscan2
- FAM90A1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 46/625 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs763937758, COSV100274199; called by muse, mutect2
- FANK1 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs371823314; called by muse, mutect2, varscan2
- FASN | c.7283G>A p.R2428H | Missense Mutation (SNP) | VAF 44/580 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.91); catalogued as rs745397050, COSV60753099; called by muse, mutect2
- FAT1 | c.6080G>A p.R2027H | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs745765579, COSV71674714; called by muse, mutect2
- FAT4 | c.11126C>T p.A3709V | Missense Mutation (SNP) | VAF 62/435 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58687294; called by muse, mutect2, varscan2
- FBXL13 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as rs201343417; called by muse, mutect2, varscan2
- FBXL16 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs191802593, COSV60965202; called by muse, mutect2, varscan2
- FBXO46 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.706); catalogued as rs755087299; called by muse, mutect2, varscan2
- FCHSD1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs767048524; called by muse, mutect2, varscan2
- FCRL2 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.119); catalogued as rs144215277, COSV100829811; called by muse, mutect2, varscan2
- FGL1 | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.63); catalogued as rs778552509; called by muse, mutect2, varscan2
- FHOD1 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 65/381 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1254418766, COSV50766273; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 26/166 reads (16%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FLII | c.563A>G p.H188R | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58947202; called by muse, mutect2, varscan2
- FNDC1 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs757314810, COSV51944192; called by muse, mutect2, varscan2
- FOXD3 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.39); catalogued as rs752440666; called by muse, mutect2, varscan2
- FRAS1 | c.5528C>T p.T1843M | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs750590926; called by muse, mutect2, varscan2
- FREM2 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1566101813, COSV99749144; called by muse, mutect2, varscan2
- FREM2 | c.9020G>A p.R3007Q | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs759757673, COSV54828636; called by mutect2, varscan2
- FRMPD3 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs776277144; called by muse, mutect2, varscan2
- FRS3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as rs746455483; called by muse, mutect2, varscan2
- FUT8 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs757041953, COSV61290953; called by muse, mutect2, varscan2
- FZD6 | c.125T>C p.F42S | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1292467728, COSV62471707; called by muse, mutect2, varscan2
- GABRA2 | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as COSV62916598, COSV62918140; called by muse, mutect2, varscan2
- GAK | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.121); catalogued as rs777181534; called by muse, mutect2, varscan2
- GALNT14 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149129327; called by muse, mutect2, varscan2
- GALNT7 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs988620410, COSV53935218; called by muse, mutect2, varscan2
- GALNT8 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV52902862; called by muse, mutect2
- GALNT9 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs782365948; called by muse, mutect2, varscan2
- GAMT | c.64del p.A22Rfs*20 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1569009071; called by mutect2, pindel
- GARRE1 | c.2599G>A p.G867S | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs757871755, COSV55105343; called by muse, mutect2, varscan2
- GAS2L1 | c.1839del p.P614Hfs*2 | Frame Shift Del (DEL) | VAF 35/231 reads (15%) | catalogued as rs78929040; called by mutect2, pindel, varscan2
- GAS2L3 | c.404T>A p.I135N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs758973803; called by muse, mutect2, varscan2
- GATD1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs781555876, COSV100168796; called by muse, mutect2, varscan2
- GCDH | c.1109T>A p.L370Q | Missense Mutation (SNP) | VAF 100/590 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as CM1414994; called by muse, mutect2, varscan2
- GCN1 | c.4631C>T p.T1544M | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.304); catalogued as rs757666642; called by muse, mutect2, varscan2
- GDF5 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 85/651 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752880147, COSV65501907; called by muse, mutect2, varscan2
- GDF5 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385244315, COSV65499959; called by muse, mutect2, varscan2
- GHITM | c.953+1G>A p.X318_splice | Splice Site (SNP) | VAF 26/137 reads (19%) | catalogued as rs202027625; called by muse, mutect2, varscan2
- GIGYF1 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs749634346; called by muse, mutect2, varscan2
- GLE1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1290402597, COSV104401604; called by muse, mutect2, varscan2
- GLUL | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754953660; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 20/81 reads (25%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAI1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs548773475, COSV63522704; called by muse, mutect2, varscan2
- GNB1L | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs767598622, COSV61547906, COSV61550112; called by muse, mutect2, varscan2
- GNGT2 | c.84G>A p.P28= | Splice Region (SNP) | VAF 33/166 reads (20%) | catalogued as rs199593250; called by muse, mutect2, varscan2
- GOLGA4 | c.5810G>A p.R1937Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs142103256; called by mutect2, varscan2
- GOSR1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1162437457, COSV56719986; called by muse, mutect2, varscan2
- GPC1 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs373679176; called by muse, mutect2, varscan2
- GPI | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 71/359 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs758132799, CM940881; called by muse, mutect2, varscan2
- GPR37L1 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 68/448 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV66162373; called by muse, mutect2, varscan2
- GPR78 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs769666701, COSV101224053; called by muse, mutect2, varscan2
- GPRC5B | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs760463381, COSV100244885, COSV56026201; called by muse, mutect2, varscan2
- GPX3 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 86/424 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs560735748, COSV59309490; called by muse, mutect2, varscan2
- GREB1 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as rs367735341; called by muse, mutect2, varscan2
- GRIA2 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs754294298, COSV52396106; called by muse, mutect2, varscan2
- GRID2 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs745635313, COSV99939417, COSV99948298; called by mutect2, varscan2
- GRIN2D | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.789); catalogued as rs772617040, COSV99474330; called by muse, mutect2, varscan2
- GRINA | c.72del p.Q26Sfs*142 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | catalogued as rs781965675; called by mutect2, pindel, varscan2
- GSX1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57232636, COSV57232889; called by muse, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | catalogued as rs750792116; called by mutect2, varscan2
- GUCY2D | c.76del p.L26Cfs*59 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as CM1410829; called by mutect2, varscan2
- H3C7 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV55101176; called by muse, mutect2, varscan2
- H4C7 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV55099758; called by muse, mutect2, varscan2
- HACD2 | c.691dup p.Q231Pfs*18 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | catalogued as rs34131865; called by mutect2, pindel, varscan2
- HACL1 | c.1123A>G p.M375V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as rs151003425; called by mutect2, varscan2
- HAGHL | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 26/196 reads (13%) | catalogued as rs747918697; called by mutect2, varscan2
- HAL | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 66/380 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); catalogued as rs139831415; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC4 | c.1574C>T p.T525M | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.964); catalogued as rs371587706; called by muse, mutect2, varscan2
- HDAC5 | c.1747del p.Q583Rfs*87 | Frame Shift Del (DEL) | VAF 35/228 reads (15%) | catalogued as COSV56819838; called by mutect2, pindel, varscan2
- HDLBP | c.3409C>T p.R1137C | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV60500265; called by muse, mutect2, varscan2
- HDLBP | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60499086; called by muse, mutect2, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 51/362 reads (14%) | catalogued as rs771658394; called by mutect2, pindel, varscan2
- HELZ2 | c.3371C>T p.A1124V (on ENST00000467148 / NM_001037335.2; = p.A555V on NM_033405.3) | Missense Mutation (SNP) | VAF 70/418 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs749328583; called by muse, mutect2, varscan2
- HEPACAM | c.427+8G>A | Splice Region (SNP) | VAF 67/459 reads (15%) | catalogued as rs1295074203, COSV53431047; called by muse, mutect2, varscan2
- HEYL | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs199521829, COSV100865356; called by muse, mutect2, varscan2
- HHIPL1 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs753259205; called by muse, mutect2, varscan2
- HIPK2 | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs764835080; called by muse, mutect2, varscan2
- HIVEP3 | c.3872C>T p.A1291V | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs146488803; called by muse, mutect2, varscan2
- HIVEP3 | c.1655C>T p.T552I | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.601); catalogued as rs774178064, COSV56009038; called by muse, mutect2, varscan2
- HM13 | c.855_857del p.K285del | In Frame Del (DEL) | VAF 33/187 reads (18%) | catalogued as rs755662149; called by pindel, varscan2
- HMCN1 | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs201162031, COSV54894219; called by muse, mutect2, varscan2
- HNF1A | c.1136del p.P379Lfs*5 | Frame Shift Del (DEL) | VAF 69/354 reads (19%) | catalogued as COSV57466638; called by mutect2, pindel, varscan2
- HNF4A | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 25/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs777727657; called by muse, mutect2
- HPS3 | c.601A>G p.M201V | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as COSV56052734; called by muse, mutect2
- HS3ST4 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.703); catalogued as rs755914455; called by muse, varscan2
- HS3ST5 | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57144870; called by muse, varscan2
- HTT | c.7238del p.P2413Hfs*44 | Frame Shift Del (DEL) | VAF 25/135 reads (19%) | catalogued as COSV100750826; called by mutect2, pindel, varscan2
- HYDIN | c.8227C>T p.R2743W | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770976118, COSV99993750; called by muse, mutect2, varscan2
- IFRD2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs587761145, COSV100269806; called by muse, mutect2, varscan2
- IGDCC4 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs775747346; called by muse, mutect2, varscan2
- IGF1R | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 92/641 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs775630539; called by muse, mutect2, varscan2
- IGHG4 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 107/620 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as rs763568423; called by muse, mutect2, varscan2
- IHH | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 115/723 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1270728079, COSV55392788; called by muse, mutect2
- IKZF2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.36); catalogued as rs754175284, COSV59577577; called by muse, mutect2, varscan2
- IL9R | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 168/872 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs200979341; called by muse, varscan2
- ILDR1 | c.1594C>T p.R532C (on ENST00000344209 / NM_001199799.2; = p.R488C on NM_175924.4) | Missense Mutation (SNP) | VAF 78/441 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs201511787; called by muse, mutect2, varscan2
- INAVA | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.551); catalogued as rs774931721; called by muse, mutect2, varscan2
- INPP4A | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs769868588, COSV50844649; called by muse, mutect2, varscan2
- ITGA2B | c.2561dup p.L855Pfs*68 | Frame Shift Ins (INS) | VAF 65/485 reads (13%) | catalogued as rs1567898633; called by mutect2, pindel, varscan2
- ITGA9 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs759937611, COSV53242831; called by muse, varscan2
- ITPR1 | c.4037A>G p.Y1346C (on ENST00000354582; = p.Y1331C on NM_002222.7) | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56983557; called by muse, mutect2, varscan2
- JAKMIP1 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.425); catalogued as rs1282195574, COSV51530755; called by muse, mutect2, varscan2
- JAZF1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs760242333, COSV52238417; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 77/496 reads (16%) | catalogued as rs774820321; called by mutect2, varscan2
- KCNA6 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 67/471 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs201648835; called by muse, mutect2, varscan2
- KCNB1 | c.2206dup p.R736Pfs*4 | Frame Shift Ins (INS) | VAF 67/353 reads (19%) | catalogued as rs759902465; called by mutect2, varscan2
- KCNB1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65569960; called by muse, mutect2, varscan2
- KCNH2 | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 128/748 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs199473426, CM057123, COSV51126911; called by muse, mutect2, varscan2
- KCNH2 | c.488T>C p.F163S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV51150674; called by mutect2, varscan2
- KCNH4 | c.642dup p.S215Vfs*39 | Frame Shift Ins (INS) | VAF 14/120 reads (12%) | catalogued as rs753954093; called by mutect2, varscan2
- KCNJ13 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs144268831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK3 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs773900452, COSV57191312; called by muse, mutect2, varscan2
- KCNN2 | c.188C>T p.A63V (on ENST00000264773; = p.A275V on NM_021614.4) | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.05); catalogued as rs758750833; called by muse, mutect2, varscan2
- KCNQ5 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 29/220 reads (13%) | catalogued as rs1369366504; called by muse, mutect2, varscan2
- KCNT1 | c.2845C>T p.R949C (on ENST00000488444; = p.R968C on NM_020822.3) | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs201987364; called by muse, mutect2, varscan2
- KDM4A | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 38/258 reads (15%) | catalogued as COSV64960352; called by muse, mutect2, varscan2
- KHSRP | c.1609C>G p.P537A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs1555726822, COSV67919748, COSV67920197; called by muse, mutect2
- KIAA0319L | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs190551485; called by muse, mutect2, varscan2
- KIAA1217 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.49); catalogued as rs147538283; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 42/252 reads (17%) | catalogued as rs752375544, COSV54318481; called by mutect2, varscan2
- KIF15 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.771); catalogued as rs145837852; called by muse, mutect2
- KIF16B | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323701527; called by muse, mutect2, varscan2
- KIF1C | c.3239del p.P1080Hfs*8 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs753993722; called by mutect2, pindel
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF21B | c.4096G>A p.V1366M (on ENST00000422435 / NM_001252100.2; = p.V1353M on NM_017596.4) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1194551347; called by muse, mutect2, varscan2
- KIF26A | c.4085del p.P1362Rfs*24 | Frame Shift Del (DEL) | VAF 38/203 reads (19%) | catalogued as rs776136395; called by mutect2, varscan2
- KIF26A | c.5356C>T p.R1786C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1328186269; called by muse, varscan2
- KIFC2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs142013461, COSV56761485; called by muse, mutect2, varscan2
- KIFC2 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as COSV100023839; called by muse, varscan2
- KIFC3 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1555622135, COSV65552475; called by muse, mutect2, varscan2
- KIR3DL2 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1176749891; called by muse, mutect2, varscan2
- KLHDC3 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs17854156; called by muse, mutect2, varscan2
- KLHDC8B | c.113del p.G38Vfs*38 | Frame Shift Del (DEL) | VAF 63/444 reads (14%) | catalogued as rs1559424362, COSV60412051; called by mutect2, pindel, varscan2
- KLHL1 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 42/315 reads (13%) | catalogued as rs1269920181, COSV64779153; called by muse, mutect2, varscan2
- KLHL22 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 54/338 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100186291; called by muse, mutect2, varscan2
- KLHL32 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 71/585 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV100987487; called by muse, mutect2, varscan2
- KMT2B | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs760508345; called by muse, mutect2, varscan2
- KMT2B | c.8026G>A p.A2676T | Missense Mutation (SNP) | VAF 76/451 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs777603343, COSV53073852; called by muse, mutect2, varscan2
- KNDC1 | c.3544G>A p.V1182M | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs777661637; called by muse, mutect2, varscan2
- KRBA1 | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as rs776668528, COSV55439698; called by muse, mutect2, varscan2
- KRT1 | c.1786G>A p.G596S | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.098); catalogued as rs1419572304, COSV52866764; called by mutect2, varscan2
- KRTAP24-1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs771391061; called by muse, mutect2, varscan2
- KSR1 | c.1388C>T p.P463L (on ENST00000644974 / NM_001367810.1; = p.P326L on NM_014238.2) | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.049); catalogued as rs748540540, COSV52031003; called by muse, mutect2, varscan2
- LAMA1 | c.6383G>A p.R2128Q | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777131128, COSV67532155; called by muse, mutect2, varscan2
- LAMB4 | c.4184C>T p.T1395M | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs187471926, COSV99063876; called by muse, mutect2, varscan2
- LAMP5 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as rs202101525; called by muse, mutect2, varscan2
- LARP1 | c.906dup p.T303Hfs*19 (on ENST00000518297 / NM_033551.3; = p.T226Hfs*19 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 36/226 reads (16%) | catalogued as rs769338468; called by mutect2, varscan2
- LARP4B | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs144611807; called by muse, mutect2, varscan2
- LARS1 | c.3017G>A p.R1006H (on ENST00000394434 / NM_020117.11; = p.R979H on NM_016460.3) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs986551702; called by muse, mutect2
- LEF1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.183); catalogued as rs199515145, COSV54467559; called by mutect2, varscan2
- LENEP | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV52696431; called by muse, mutect2
- LGR6 | c.2518C>T p.R840W (on ENST00000367278 / NM_001017403.1; = p.R788W on NM_021636.3) | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.676); catalogued as rs146290853; called by muse, mutect2, varscan2
- LILRA1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 67/458 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as rs529375145, COSV52184940; called by muse, mutect2, varscan2
- LMCD1 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 75/500 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747063865, COSV50089010; called by muse, mutect2, varscan2
- LMNTD2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs758825364; called by muse, mutect2, varscan2
- LMTK3 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs188431208; called by muse, mutect2, varscan2
- LOXL2 | c.2276del p.K759Sfs*9 | Frame Shift Del (DEL) | VAF 33/155 reads (21%) | catalogued as rs765428971; called by mutect2, pindel, varscan2
- LPAR5 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs757376713, COSV100321090; called by muse, mutect2, varscan2
- LPCAT1 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs764493318; called by muse, mutect2, varscan2
- LRCH4 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs746804965, COSV56166431; called by muse, mutect2, varscan2
- LRIG1 | c.2150C>T p.T717M | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs757878940, COSV56239849; called by muse, mutect2, varscan2
- LRP1 | c.11257C>T p.R3753C | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs771090395, COSV54527892; called by muse, mutect2, varscan2
- LRP1 | c.12575del p.P4192Qfs*150 | Frame Shift Del (DEL) | VAF 25/130 reads (19%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP5 | c.4226G>A p.R1409H | Missense Mutation (SNP) | VAF 64/415 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765378705, COSV99592308; called by muse, mutect2, varscan2
- LRP5 | c.4757C>T p.A1586V | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs767157733; called by muse, mutect2, varscan2
- LRRC4B | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs762762398, COSV100975918; called by muse, mutect2, varscan2
- LRRC53 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 49/368 reads (13%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.598); catalogued as rs562229075; called by muse, mutect2, varscan2
- LRRN4CL | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs1484812817; called by muse, mutect2, varscan2
- LRRTM3 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.123); catalogued as COSV63672772; called by muse, mutect2, varscan2
- LTBP3 | c.3692G>A p.R1231Q (on ENST00000301873 / NM_001130144.3; = p.R1184Q on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.859); catalogued as COSV99534819; called by muse, mutect2, varscan2
- LZTR1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 53/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768361273, COSV53150648; called by muse, mutect2, varscan2
- MACF1 | c.8572C>T p.R2858C | Missense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as rs764967333, COSV57129481; called by muse, mutect2, varscan2
- MADD | c.3103G>A p.A1035T | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60620761; called by muse, mutect2, varscan2
- MAGEE2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1485986885; called by muse, mutect2, varscan2
- MAGEH1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV61679184; called by muse, mutect2, varscan2
- MAGI1 | c.4226G>A p.R1409H | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as rs1471775161, COSV100439812; called by muse, mutect2, varscan2
- MAK16 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs374295616; called by muse, mutect2, varscan2
- MANBAL | c.150G>A p.A50= | Splice Region (SNP) | VAF 21/90 reads (23%) | catalogued as rs772634121; called by muse, mutect2, varscan2
- MAP3K10 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs746524729; called by muse, mutect2, varscan2
- MAP7D1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202003056; called by muse, mutect2, varscan2
- MARCHF2 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs200200875, COSV53104371; called by muse, mutect2, varscan2
- MATK | c.146C>T p.P49L (on ENST00000310132 / NM_139355.3; = p.P50L on NM_002378.4) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs1268544920, COSV59556366; called by muse, mutect2, varscan2
- MBD2 | c.471dup p.G158Rfs*28 | Frame Shift Ins (INS) | VAF 18/79 reads (23%) | catalogued as rs755716804; called by mutect2, varscan2
- MC3R | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 77/495 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs760254173, COSV54763308, COSV54763803; called by muse, mutect2, varscan2
- MCM10 | c.1702C>T p.R568W (on ENST00000484800 / NM_182751.3; = p.R567W on NM_018518.5) | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs761494277; called by muse, mutect2, varscan2
- MCM3AP | c.5585C>T p.A1862V | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs772612320, COSV52442791; called by muse, mutect2, varscan2
- MCM7 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772981794; called by muse, mutect2
- MCM8 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs200653375, COSV54511439; called by muse, varscan2
- MCU | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs536802096; called by muse, mutect2, varscan2
- MDH2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as rs141539461; called by muse, mutect2, varscan2
- MET | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs587778443, COSV99041950; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- METTL22 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757385549, COSV99371834; called by muse, mutect2, varscan2
- MEX3D | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752546270; called by muse, mutect2, varscan2
- MFSD13A | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as rs376006315; called by muse, mutect2, varscan2
- MFSD2A | c.1097G>A p.R366Q (on ENST00000372809 / NM_001136493.3; = p.R353Q on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs540449746, COSV65685296; called by muse, mutect2, varscan2
- MFSD6L | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61002565; called by muse, mutect2, varscan2
- MGAT4B | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs932687966; called by muse, mutect2, varscan2
- MGST3 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1437778946; called by muse, mutect2, varscan2
- MIB2 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749010894; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 20/168 reads (12%) | catalogued as rs765803753; called by mutect2, varscan2
- MIDEAS | c.3126del p.K1042Nfs*51 | Frame Shift Del (DEL) | VAF 46/207 reads (22%) | catalogued as rs1168947806; called by mutect2, pindel, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIGA2 | c.420G>A p.S140= | Splice Region (SNP) | VAF 45/163 reads (28%) | catalogued as rs377014367; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs750307488; called by mutect2, varscan2
- MKNK1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs756358006; called by muse, varscan2
- MMP2 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 78/519 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1022088103, COSV54605220; called by muse, mutect2, varscan2
- MMRN2 | c.654C>T p.H218= | Splice Region (SNP) | VAF 25/138 reads (18%) | catalogued as rs140040286; called by muse, mutect2, varscan2
- MMS19 | c.1219-7G>A | Splice Region (SNP) | VAF 17/113 reads (15%) | catalogued as rs367722662; called by muse, mutect2, varscan2
- MOB3C | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1169802084, COSV54718985; called by muse, mutect2, varscan2
- MPL | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 73/452 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs368753117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPRIP | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1175028801; called by muse, mutect2, varscan2
- MRPL38 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs371715586; called by muse, mutect2, varscan2
- MRPL55 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 40/281 reads (14%) | catalogued as rs759317636, COSV54342482; called by muse, mutect2, varscan2
- MRPS31 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs868622225, COSV60266601; called by muse, mutect2, varscan2
- MRTFB | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs115834470; called by mutect2, varscan2
- MSH6 | c.3284G>A p.R1095H | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs63750253, CM030237, COSV52274456; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MTO1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs199913708, COSV100940301; called by muse, mutect2, varscan2
- MUC16 | c.13729G>A p.A4577T | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs372775227; called by muse, mutect2, varscan2
- MUC16 | c.6762del p.S2255Pfs*6 | Frame Shift Del (DEL) | VAF 35/278 reads (13%) | catalogued as rs776993869, COSV67451814; called by mutect2, pindel, varscan2
- MUC5B | c.5086C>T p.R1696C | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as rs777860574; called by muse, mutect2, varscan2
- MUC5B | c.13675G>A p.V4559I | Missense Mutation (SNP) | VAF 90/592 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs766036125, COSV71594611; called by muse, mutect2, varscan2
- MYG1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.108); catalogued as rs775086535, COSV52932698; called by muse, mutect2, varscan2
- MYH1 | c.5422G>A p.A1808T | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV56857151; called by muse, mutect2, varscan2
- MYH3 | c.4897G>A p.A1633T | Missense Mutation (SNP) | VAF 43/416 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs374056469, COSV56860469; called by muse, mutect2, varscan2
- MYH9 | c.5677C>T p.R1893C | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1015157301, COSV53385930, COSV53388726, COSV53395303; called by muse, mutect2, varscan2
- MYL12A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs1348224743; called by muse, mutect2
- MYO18A | c.2302G>A p.V768I | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs749076838, COSV62871599; called by muse, mutect2, varscan2
- MYO1G | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.575); catalogued as rs767632037, COSV51853017; called by muse, mutect2, varscan2
- MYOM1 | c.4522G>A p.G1508R | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780730209, COSV55295243; called by muse, mutect2, varscan2
- MYOM3 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 26/174 reads (15%) | catalogued as rs547592318; called by muse, mutect2, varscan2
- MYORG | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.295); catalogued as rs1563983136; called by muse, mutect2, varscan2
- NAA25 | c.875_877del p.E292del | In Frame Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs745904144; called by mutect2, pindel, varscan2
- NAE1 | c.620del p.K207Rfs*10 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs1401721531; called by mutect2, varscan2
- NAIF1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 119/772 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs764083368; called by muse, mutect2, varscan2
- NCKAP1L | c.213G>A p.T71= | Splice Region (SNP) | VAF 18/99 reads (18%) | catalogued as rs778692151, COSV53203896; called by muse, mutect2, varscan2
- NCOA6 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1330771895, COSV100750465, COSV62862902; called by muse, mutect2, varscan2
- NCOR1 | c.6641G>A p.R2214H | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs142105041; called by muse, mutect2, varscan2
- NECTIN2 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs770078525; called by muse, mutect2, varscan2
- NEFM | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV99647092; called by muse, mutect2, varscan2
- NEK6 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs1386167089; called by muse, mutect2, varscan2
- NEO1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs142363521; called by muse, mutect2, varscan2
- NEXN | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs761451693; called by muse, mutect2, varscan2
- NISCH | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.056); catalogued as rs1215041643, COSV104422773; called by muse, mutect2, varscan2
- NIT1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 69/434 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100919041, COSV63501315; called by muse, mutect2, varscan2
- NLN | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs763162614, COSV66764931; called by muse, varscan2
- NLRC5 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs202133400; called by muse, mutect2, varscan2
- NOS1 | c.3385C>T p.R1129C | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs772708191, COSV57607600; called by muse, mutect2, varscan2
- NOS2 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs201529188; called by muse, mutect2, varscan2
- NOTCH2 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 86/460 reads (19%) | catalogued as COSV99865565; called by mutect2, varscan2
- NOTUM | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 64/350 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776135176, COSV68826274; called by muse, mutect2, varscan2
- NOXO1 | c.835T>C p.Y279H (on ENST00000397280 / NM_172168.3; = p.Y273H on NM_144603.4) | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs1284110457; called by muse, mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 10/99 reads (10%) | catalogued as rs35747263; called by mutect2, pindel
- NPR1 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 55/347 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332700324; called by muse, mutect2, varscan2
- NPR2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs920376052, COSV61309591; called by muse, mutect2, varscan2
- NPTX2 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as rs936955349, COSV55718362; called by muse, mutect2, varscan2
- NRXN2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs1432184680, COSV55448205, COSV55463489; called by muse, mutect2, varscan2
- NSDHL | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100938581; called by muse, mutect2
- NSUN4 | c.367T>C p.W123R | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1366744582; called by muse, mutect2, varscan2
- OBSL1 | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs768202370, COSV54722904; called by muse, mutect2, varscan2
- OLIG3 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1213301174; called by muse, mutect2, varscan2
- OR10Q1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs1554976493, COSV57469961; called by muse, mutect2
- OR1L1 | c.515G>A p.R172H (on ENST00000373686; = p.R122H on NM_001005236.3) | Missense Mutation (SNP) | VAF 127/401 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs758410477, COSV100542135, COSV58937123; called by muse, mutect2, varscan2
- OR2A4 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 26/148 reads (18%) | catalogued as rs763408926; called by mutect2, varscan2
- OR2J2 | c.197A>C p.N66T | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV101013332; called by muse, mutect2
- OR4C46 | c.90dup p.V31Cfs*38 | Frame Shift Ins (INS) | VAF 24/165 reads (15%) | catalogued as rs759167019; called by mutect2, pindel, varscan2
- OR52A1 | c.814del p.S272Pfs*36 | Frame Shift Del (DEL) | VAF 32/206 reads (16%) | catalogued as rs1342694715, COSV61092188; called by mutect2, pindel, varscan2
- OR56A4 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV58110087; called by muse, mutect2, varscan2
- OR5D18 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 77/530 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488665846, COSV61736999; called by muse, mutect2, varscan2
- OSBPL6 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1207661650, COSV99507612; called by muse, mutect2, varscan2
- OTUD7B | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs369467490; called by muse, mutect2, varscan2
- OXTR | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as rs1457871248; called by muse, mutect2, varscan2
- P3H3 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373813652; called by muse, mutect2, varscan2
- PACRGL | c.609C>T p.S203= | Splice Region (SNP) | VAF 14/141 reads (10%) | catalogued as rs866008161, COSV54841489, COSV99764396; called by muse, mutect2
- PACS2 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.297); catalogued as rs782592280, COSV100330830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by mutect2, varscan2
- PAOX | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1472318687, COSV53371964; called by muse, mutect2, varscan2
- PARD3 | c.3217C>T p.R1073* | Nonsense Mutation (SNP) | VAF 23/178 reads (13%) | catalogued as rs1380603624, COSV100630742, COSV100633538; called by muse, mutect2, varscan2
- PARD6G | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1420192450, COSV62060403; called by muse, mutect2, varscan2
- PARVB | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs750085183; called by muse, mutect2, varscan2
- PCDH17 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 102/520 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64974096; called by muse, mutect2, varscan2
- PCDH17 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 77/368 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1225886813, COSV64977246; called by muse, mutect2, varscan2
- PCDHA1 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 157/820 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782390753, COSV65372701, COSV65374167; called by muse, mutect2, varscan2
- PCDHA13 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 104/872 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56504604; called by mutect2, varscan2
- PCDHB5 | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 132/782 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50652564, COSV99167683; called by muse, mutect2, varscan2
- PCDHB8 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 108/1622 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.05); catalogued as rs782643110, COSV50762098; called by muse, mutect2
- PCDHGA7 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as COSV53933169; called by muse, mutect2, varscan2
- PCDHGB3 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV53958553; called by muse, mutect2, varscan2
- PCDHGC5 | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 53/297 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs975297143; called by muse, mutect2, varscan2
- PCED1B | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.051); catalogued as rs1279810981, COSV71395259; called by muse, mutect2, varscan2
- PCMTD2 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 55/439 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs769714581; called by muse, mutect2, varscan2
- PCNX3 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750506857; called by muse, varscan2
- PDCD1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 76/528 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs190602950, COSV57690777; called by muse, varscan2
- PDCD11 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs527328139, COSV63933974; called by muse, mutect2, varscan2
- PDLIM2 | c.764-8G>A | Splice Region (SNP) | VAF 60/366 reads (16%) | catalogued as rs748836861; called by muse, mutect2, varscan2
- PDLIM4 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 110/718 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.795); catalogued as rs867265087, COSV53803954, COSV99516804; called by muse, mutect2, varscan2
- PDS5A | c.2935C>T p.R979C | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758225510, COSV57827007; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs759495724; called by mutect2, varscan2
- PELI3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs143638418, COSV57858108; called by muse, mutect2, varscan2
- PEX1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs769114978, COSV50397929; called by muse, mutect2, varscan2
- PFKFB2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 28/220 reads (13%) | PolyPhen probably damaging (0.988); catalogued as rs1335499341, COSV65548814; called by muse, mutect2, varscan2
- PFKFB3 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 23/179 reads (13%) | PolyPhen probably damaging (0.999); catalogued as rs764975677, COSV100432204, COSV57990455; called by muse, mutect2, varscan2
- PGLS | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1321600951, COSV53114636; called by muse, mutect2, varscan2
- PHACTR4 | c.1076del p.P359Lfs*20 (on ENST00000373839 / NM_001350159.2; = p.P369Lfs*20 on NM_023923.4) | Frame Shift Del (DEL) | VAF 39/294 reads (13%) | catalogued as COSV65785300; called by mutect2, pindel, varscan2
- PHGDH | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1013027843; called by muse, mutect2
- PINX1 | c.474C>T p.G158= | Splice Region (SNP) | VAF 36/220 reads (16%) | catalogued as rs762236736, COSV59108431; called by muse, mutect2, varscan2
- PIWIL1 | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55344013; called by muse, mutect2, varscan2
- PKD1 | c.5848G>A p.V1950M | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs771669643, COSV99237014; called by muse, mutect2, varscan2
- PKDREJ | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs757965249, COSV53546237; called by muse, mutect2, varscan2
- PKDREJ | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs772301557, COSV53546327; called by muse, mutect2, varscan2
- PKN3 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749266685; called by muse, mutect2, varscan2
- PKNOX2 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); catalogued as rs762099105, COSV53543136; called by muse, mutect2, varscan2
- PLA2G4C | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs375044049; called by muse, mutect2, varscan2
- PLA2G4F | c.2014A>G p.M672V | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as rs369850151; called by muse, mutect2, varscan2
- PLA2G6 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 67/482 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs367854265; called by muse, mutect2, varscan2
- PLAAT2 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 69/436 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs372878699; called by muse, mutect2, varscan2
- PLB1 | c.3659C>T p.P1220L | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as rs750173393; called by muse, mutect2, varscan2
- PLCH2 | c.2898del p.G969Dfs*77 | Frame Shift Del (DEL) | VAF 23/128 reads (18%) | catalogued as rs756194318; called by mutect2, pindel, varscan2
- PLEC | c.9343C>T p.R3115C (on ENST00000322810 / NM_201380.4; = p.R3005C on NM_000445.5) | Missense Mutation (SNP) | VAF 133/586 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs782297488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.1131C>T p.D377= (on ENST00000322810 / NM_201380.4; = p.D267= on NM_000445.5) | Splice Region (SNP) | VAF 29/833 reads (3%) | catalogued as rs782638021, COSV59639702, COSV59658421; called by muse, mutect2
- PLEKHG3 | c.776G>A p.R259H (on ENST00000394691; = p.R315H on NM_001308147.2) | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs775178166, COSV55978878; called by muse, mutect2, varscan2
- PLEKHO2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs201913666; called by muse, mutect2, varscan2
- PLK1 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs775897156, CM157010, COSV55623244; called by muse, varscan2
- PLK3 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 75/516 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218450172, COSV59499541; called by muse, mutect2, varscan2
- PLK4 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs753397524; called by muse, mutect2, varscan2
- PLPP7 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146871462, COSV64835992; called by muse, mutect2, varscan2
- PLXNA1 | c.4249G>A p.E1417K | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs146629329; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 64/154 reads (42%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNB1 | c.3222G>A p.S1074= | Splice Region (SNP) | VAF 57/276 reads (21%) | catalogued as rs751454294, COSV56489665; called by muse, mutect2, varscan2
- PMFBP1 | c.2855_2857del p.K952del (on ENST00000537465; = p.K947del on NM_031293.3) | In Frame Del (DEL) | VAF 48/270 reads (18%) | catalogued as rs746555224; called by pindel, varscan2
- PMPCA | c.354G>A p.S118= | Splice Region (SNP) | VAF 15/59 reads (25%) | catalogued as rs758657485, COSV53743248; called by muse, mutect2, varscan2
- PMVK | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as rs779946272; called by muse, mutect2, varscan2
- PNISR | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 21/174 reads (12%) | catalogued as COSV65078640; called by muse, mutect2, varscan2
- PODN | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753880782; called by muse, mutect2, varscan2
- POLE | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs192173820; called by muse, mutect2, varscan2
- POLM | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 82/451 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54242207; called by muse, mutect2, varscan2
- POLRMT | c.3323G>A p.R1108Q | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749393748; called by muse, mutect2, varscan2
- PPL | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs749453551; called by muse, mutect2, varscan2
- PPP1R16A | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.195); catalogued as rs148405688; called by muse, mutect2, varscan2
- PRAME | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751654581, COSV67160962, COSV67161098; called by muse, mutect2, varscan2
- PRDM10 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 14/189 reads (7%) | catalogued as rs776979992; called by muse, mutect2
- PREX1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766440280; called by muse, mutect2, varscan2
- PRICKLE2 | c.1090C>T p.R364W (on ENST00000295902; = p.R308W on NM_198859.4) | Missense Mutation (SNP) | VAF 98/596 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1465780206; called by muse, mutect2, varscan2
- PRKCD | c.1300del p.D434Tfs*2 | Frame Shift Del (DEL) | VAF 32/179 reads (18%) | catalogued as rs1559629912, COSV57847601; called by mutect2, varscan2
- PROSER3 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as rs778194260; called by muse, mutect2, varscan2
- PRRC2A | c.6469C>T p.R2157C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs781602439, COSV52991027, COSV99277245; called by muse, varscan2
- PRRC2B | c.430T>C p.W144R | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs989832455; called by muse, mutect2, varscan2
- PRRC2B | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs371863600; called by muse, mutect2, varscan2
- PRRC2C | c.2245C>T p.R749* (on ENST00000367742; = p.R747* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 20/153 reads (13%) | catalogued as COSV58911656; called by muse, mutect2, varscan2
- PRRC2C | c.6799G>A p.E2267K (on ENST00000367742; = p.E2265K on NM_015172.4) | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100144452; called by muse, mutect2, varscan2
- PTCH1 | c.2015C>T p.T672M | Missense Mutation (SNP) | VAF 87/548 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.938); catalogued as rs372219420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD4 | c.1441G>T p.G481W | Missense Mutation (SNP) | VAF 17/355 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104412824; called by muse, mutect2
- PTPN21 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs112928496, COSV60850408; called by muse, mutect2, varscan2
- PTPN7 | c.124C>T p.R42W (on ENST00000495688; = p.R81W on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200332945, COSV58311526, COSV58313174; called by muse, mutect2, varscan2
- PTPRN | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 33/140 reads (24%) | catalogued as COSV55345328; called by muse, mutect2, varscan2
- PTPRS | c.3041C>T p.T1014M | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1391073074, COSV53628505; called by muse, mutect2, varscan2
- PTPRT | c.4073G>A p.R1358Q | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs180871064, COSV61965505; called by muse, mutect2, varscan2
- PTPRT | c.2847C>T p.D949= | Splice Region (SNP) | VAF 16/96 reads (17%) | catalogued as rs372525279; called by muse, mutect2, varscan2
- PXDNL | c.4075del p.T1359Qfs*25 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs1252570521; called by mutect2, pindel, varscan2
- PXDNL | c.3019G>A p.A1007T | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62500359; called by muse, mutect2, varscan2
- PYGM | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 61/381 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370291854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QPRT | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs968087762; called by muse, mutect2
- QRICH2 | c.4957G>A p.A1653T | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as rs750047159; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3387del p.A1130Pfs*50 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | catalogued as rs752866106; called by mutect2, varscan2
- RAB31 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs200908119; called by muse, mutect2, varscan2
- RAI1 | c.4936G>A p.G1646R | Missense Mutation (SNP) | VAF 53/375 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.437); catalogued as rs143029873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALGDS | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 128/470 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs755889399; called by muse, mutect2, varscan2
- RALGDS | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 187/634 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs377532288; called by muse, mutect2, varscan2
- RANGAP1 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.527); catalogued as rs1248671879, COSV62363397; called by muse, mutect2, varscan2
- RARG | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751844553; called by muse, mutect2, varscan2
- RASAL1 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs372608661; called by muse, mutect2, varscan2
- RASSF1 | c.372C>T p.D124= (on ENST00000357043 / NM_170714.2; = p.D120= on NM_007182.5) | Splice Region (SNP) | VAF 18/137 reads (13%) | catalogued as rs775856929; called by muse, mutect2, varscan2
- RAVER1 | c.1071del p.K358Sfs*177 (on ENST00000615032; = p.K358Sfs*149 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | catalogued as rs773370779, COSV99532335; called by mutect2, pindel
- RBM42 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as rs376033321; called by muse, varscan2
- RCOR3 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs145735878; called by muse, mutect2, varscan2
- RESP18 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1430052499; called by muse, mutect2
- RFTN1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 76/459 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs745806714, COSV61919531; called by muse, mutect2, varscan2
- RFX3 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs191847028; called by muse, mutect2, varscan2
- RGR | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 68/478 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs558105831, COSV100812994; called by muse, varscan2
- RHOV | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs767785165; called by muse, mutect2, varscan2
- RHOXF2B | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs781983826; called by muse, mutect2, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 56/250 reads (22%) | catalogued as rs760343057; called by mutect2, varscan2
- RMDN3 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747144620; called by muse, mutect2, varscan2
- RMDN3 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764325803; called by muse, mutect2, varscan2
- RNASET2 | c.446+1G>A p.X149_splice | Splice Site (SNP) | VAF 85/652 reads (13%) | catalogued as rs1197491948; called by muse, mutect2, varscan2
- RNPEPL1 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs768452852; called by muse, mutect2, varscan2
- ROBO3 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs745697799; called by muse, mutect2, varscan2
- RP1L1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 88/501 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs750793578; called by muse, mutect2, varscan2
- RPL11 | c.433C>T p.R145C (on ENST00000374550 / NM_001199802.1; = p.R146C on NM_000975.5) | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1001063696, COSV65779057; called by muse, mutect2, varscan2
- RPL28 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs981850816; called by muse, mutect2, varscan2
- RRP1B | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs142705199; called by muse, mutect2, varscan2
- RSPH6A | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as rs369485410, COSV55571017; called by muse, mutect2, varscan2
- RSPO3 | c.666del p.K222Nfs*62 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs1049009076; called by mutect2, pindel
- RTL5 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1326767228, COSV101029830; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs756606313; called by mutect2, varscan2
- RUNDC1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 33/186 reads (18%) | catalogued as rs746353875; called by muse, mutect2, varscan2
- RUNX1 | c.802_804del p.S268del (on ENST00000344691 / NM_001001890.3; = p.S295del on NM_001754.5) | In Frame Del (DEL) | VAF 51/364 reads (14%) | catalogued as rs771972670; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RUVBL2 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767467214, COSV55487128; called by muse, mutect2, varscan2
- RWDD2B | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1362089838; called by muse, mutect2, varscan2
- RYR3 | c.6889C>T p.R2297C (on ENST00000389232; = p.R2298C on NM_001036.6) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757487919, COSV63109571; called by muse, mutect2, varscan2
- SACS | c.5967G>C p.K1989N | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV66547191; called by muse, mutect2, varscan2
- SALL2 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746092722, COSV100444523, COSV58103814; called by muse, mutect2, varscan2
- SAMD7 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs750348887, COSV100157021; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 31/204 reads (15%) | catalogued as COSV59083791; called by mutect2, varscan2
- SARDH | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as rs758427155; called by muse, mutect2, varscan2
- SART3 | c.1531C>T p.R511W (on ENST00000228284; = p.R493W on NM_014706.4) | Missense Mutation (SNP) | VAF 86/568 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377925264; called by muse, mutect2, varscan2
- SATB2 | c.598-4del | Splice Region (DEL) | VAF 20/64 reads (31%) | catalogued as rs199978702; ClinVar: benign / likely benign; called by mutect2, varscan2
- SBF1 | c.2429C>T p.T810M | Missense Mutation (SNP) | VAF 55/397 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs754556678, COSV62365529; called by muse, mutect2, varscan2
- SBNO1 | c.3836A>G p.H1279R (on ENST00000420886; = p.H1278R on NM_018183.5) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57343063; called by muse, mutect2, varscan2
- SBNO1 | c.764G>A p.R255H (on ENST00000420886; = p.R254H on NM_018183.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.915); catalogued as rs1328114976, COSV57342629; called by muse, mutect2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | catalogued as rs765136101; called by pindel, varscan2
- SCRIB | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752702092, COSV100253786; called by muse, mutect2, varscan2
- SEMA5B | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52093632; called by muse, varscan2
- SENP3 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs1403465609; called by muse, mutect2, varscan2
- SERF2 | c.163_165del p.K55del | In Frame Del (DEL) | VAF 38/226 reads (17%) | catalogued as rs763552438; called by pindel, varscan2
- SERTAD2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 85/455 reads (19%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs772856400, COSV57641417; called by muse, mutect2, varscan2
- SETD1B | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV57349993; called by muse, mutect2, varscan2
- SETD2 | c.4501T>C p.C1501R | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57439746, COSV57444879; called by muse, mutect2, varscan2
- SETX | c.3755del p.G1252Dfs*9 | Frame Shift Del (DEL) | VAF 21/232 reads (9%) | catalogued as rs1275836821; called by mutect2, pindel
- SEZ6L2 | c.2512C>T p.R838W (on ENST00000308713 / NM_001114099.3; = p.R781W on NM_012410.4) | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs749785731, COSV58098093; called by muse, mutect2, varscan2
- SGSH | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 107/614 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs575904470, COSV58340513; called by muse, mutect2, varscan2
- SH2D3C | c.671G>A p.R224H (on ENST00000314830 / NM_170600.3; = p.R67H on NM_005489.4) | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs772668891, COSV59123471; called by muse, mutect2, varscan2
- SH3TC1 | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.119); catalogued as rs761154989, COSV55281678, COSV55286909; called by muse, mutect2, varscan2
- SHPRH | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 58/419 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV51610529; called by muse, mutect2, varscan2
- SIDT1 | c.836-7A>T | Splice Region (SNP) | VAF 5/47 reads (11%) | catalogued as rs1235334284; called by muse, varscan2
- SIGLEC1 | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 36/369 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104390140; called by muse, mutect2
- SIGLEC5 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 59/413 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as rs1360404047; called by muse, mutect2, varscan2
- SIN3A | c.3146C>T p.T1049M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs772526843, COSV64582129; called by muse, mutect2, varscan2
- SIRT2 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752774292, COSV50878955; called by muse, mutect2
- SIRT6 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1197840997, COSV59446619; called by muse, mutect2, varscan2
- SKOR1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs865884747, COSV58246536; called by muse, mutect2, varscan2
- SLC11A2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/95 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as rs1333848071; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC15A4 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as rs942446529, COSV57160445, COSV99903745; called by muse, mutect2
- SLC18A1 | c.1445dup p.A483Gfs*36 | Frame Shift Ins (INS) | VAF 9/86 reads (10%) | catalogued as rs754303620; called by mutect2, pindel, varscan2
- SLC1A7 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101020032; called by muse, mutect2, varscan2
- SLC22A7 | c.1504G>A p.A502T (on ENST00000372585 / NM_153320.2; = p.A500T on NM_006672.3) | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as rs201403046, COSV51482725; called by muse, mutect2, varscan2
- SLC26A1 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs558027930, COSV56104355; called by muse, mutect2, varscan2
- SLC26A3 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as rs1479983912, COSV60641169; called by muse, mutect2, varscan2
- SLC35F3 | c.694G>A p.V232I (on ENST00000366617 / NM_001300845.1; = p.V301I on NM_173508.4) | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.23); catalogued as rs373070068; called by muse, mutect2, varscan2
- SLC36A3 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs750544349; called by muse, mutect2, varscan2
- SLC4A7 | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM142760, COSV55395452; called by muse, mutect2, varscan2
- SLC5A3 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs191539072; called by muse, mutect2, varscan2
- SLC7A1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs758124150; called by muse, mutect2
- SLCO2A1 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369396153; called by muse, mutect2, varscan2
- SLIT2 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs200224686, COSV56560139; called by muse, mutect2, varscan2
- SLITRK1 | c.134del p.K45Rfs*64 | Frame Shift Del (DEL) | VAF 20/143 reads (14%) | catalogued as COSV65676896; called by mutect2, pindel, varscan2
- SMARCA4 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 66/366 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs1227659334, COSV60809546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCR8 | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371878387; called by muse, mutect2, varscan2
- SMTNL1 | c.823G>A p.D275N (on ENST00000399154; = p.D312N on NM_001105565.2) | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs375079476; called by muse, mutect2, varscan2
- SNED1 | c.*1+4C>T | Splice Region (SNP) | VAF 14/146 reads (10%) | catalogued as rs376903624; called by muse, mutect2
- SNRNP25 | c.284C>T p.T95M (on ENST00000383018; = p.T86M on NM_024571.4) | Missense Mutation (SNP) | VAF 71/326 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs554678630; called by muse, mutect2, varscan2
- SNX7 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs756173460; called by muse, mutect2, varscan2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel, varscan2
- SORBS2 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 65/507 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52995768; called by muse, mutect2, varscan2
- SOX13 | c.1116del p.N373Tfs*33 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | catalogued as COSV65826522; called by mutect2, pindel, varscan2
- SP110 | c.1691del p.P564Lfs*16 | Frame Shift Del (DEL) | VAF 66/386 reads (17%) | catalogued as rs1245290762; called by mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 24/112 reads (21%) | catalogued as rs746109620; called by mutect2, varscan2
- SPARCL1 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201942856; called by muse, mutect2, varscan2
- SPATA20 | c.1897C>T p.R633C (on ENST00000356488 / NM_001258372.1; = p.R649C on NM_022827.4) | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs755985686, COSV50066383; called by muse, mutect2, varscan2
- SPATA31A1 | c.3887G>A p.C1296Y | Missense Mutation (SNP) | VAF 76/523 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.062); catalogued as rs1200496427; called by muse, mutect2, varscan2
- SPATA31D3 | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1441143441; called by mutect2, varscan2
- SPEG | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs767356198; called by muse, mutect2, varscan2
- SPEN | c.10132G>A p.G3378S | Missense Mutation (SNP) | VAF 69/397 reads (17%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as rs375688033; called by muse, mutect2, varscan2
- SPHK1 | c.901C>T p.R301C (on ENST00000392496 / NM_001355139.2; = p.R315C on NM_021972.4) | Missense Mutation (SNP) | VAF 78/459 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs767050341; called by muse, mutect2, varscan2
- SPIRE2 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.52); catalogued as rs145719560, COSV65554166; called by muse, mutect2, varscan2
- SPOCK3 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.274); catalogued as rs767849456; called by muse, mutect2, varscan2
- SPTBN5 | c.4939C>T p.P1647S | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1357368494; called by muse, mutect2, varscan2
- SREK1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as rs773818045; called by muse, mutect2, varscan2
- SRRT | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1395459534, COSV100730008; called by muse, mutect2, varscan2
- SRSF11 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV63936628; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 74/267 reads (28%) | PolyPhen probably damaging (0.917); catalogued as rs764607427, COSV100231617; called by muse, mutect2, varscan2
- STK31 | c.675del p.K225Nfs*35 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | catalogued as rs746386632, COSV63453772; called by mutect2, varscan2
- STMN3 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs556068883, COSV100899847; called by muse, mutect2, varscan2
- STOX1 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746444738; called by muse, mutect2, varscan2
- STX17 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs75046158, COSV52285556, COSV99407819; called by muse, mutect2, varscan2
- SULF1 | c.1383G>A p.W461* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99484273; called by muse, varscan2
- SUPT3H | c.598C>T p.R200* (on ENST00000371460 / NM_181356.3; = p.R189* on NM_003599.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as rs781512633, COSV60933383; called by muse, mutect2, varscan2
- SYT14 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs375826096; called by muse, mutect2, varscan2
- SZT2 | c.5831C>T p.P1944L (on ENST00000634258 / NM_001365999.1; = p.P1887L on NM_015284.4) | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs754585816, COSV65170447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SZT2 | c.9197G>A p.R3066Q (on ENST00000634258 / NM_001365999.1; = p.R3009Q on NM_015284.4) | Missense Mutation (SNP) | VAF 76/424 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as rs547140528, COSV100981193, COSV65095037; called by muse, mutect2, varscan2
- TAF1C | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs545517827, COSV58986611; called by muse, mutect2, varscan2
- TAP2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 109/631 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as rs758423176, COSV66499929; called by muse, mutect2, varscan2
- TAPT1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs376072922; called by muse, mutect2, varscan2
- TAS1R2 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 68/533 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528333669, COSV64745579; called by muse, mutect2, varscan2
1,479 further variants in this file (746 protein-altering or splice-affecting, 476 silent, 257 other) are not listed here.
